Somatic mutation profile of tumor specimen ALCH-B2TF-TTP1-A (aliquot ALCH-B2TF-TTP1-A-1-0-D-A77K-36) from ALCHEMIST case ALCH-B2TF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.8 years (24,047 days).
Specimen ALCH-B2TF-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12038245-3948-4332-a163-d1295cf38f74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2TF-NB1-A (Blood Derived Normal), aliquot ALCH-B2TF-NB1-A-1-0-D-A77K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a54f426-6c8c-465b-a9e4-a029d47e3dd2

The open-access MAF lists 57 somatic variants for this specimen: 39 protein-altering or splice-affecting, 12 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 12, Frame Shift Del 3, Intron 2, Splice Site 2, 5'Flank 2, Nonsense Mutation 2, Splice Region 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 209/580 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ADCY5 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs746695130; called by muse, mutect2, varscan2
- AP2A2 | c.2799A>C p.E933D | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1197557336; called by muse, mutect2, varscan2
- AVIL | c.141G>A p.S47= | Splice Region (SNP) | VAF 22/145 reads (15%) | catalogued as rs146606222; called by muse, mutect2, varscan2
- B3GALT5 | c.670G>A p.D224N | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751818934; called by muse, mutect2, varscan2
- CBLB | c.1204-2A>T p.X402_splice | Splice Site (SNP) | VAF 20/223 reads (9%) | catalogued as rs771912484; called by muse, mutect2
- CNTNAP4 | c.3674C>G p.T1225R | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV56694877; called by muse, mutect2
- CPA2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1347114813; called by muse, mutect2
- CYP4F8 | c.686G>C p.S229T | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.361); catalogued as rs775341868, COSV57855682; called by muse, mutect2
- ETFDH | c.1505G>A p.C502Y | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.145); catalogued as rs760679984; called by muse, mutect2
- GDF9 | c.1012A>G p.N338D | Missense Mutation (SNP) | VAF 11/247 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.092); catalogued as rs1274477034; called by muse, mutect2
- IKZF1 | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 54/663 reads (8%) | catalogued as COSV58791001; called by muse, mutect2
- ITPRID2 | c.1085A>T p.E362V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776527250, COSV57472026; called by mutect2, varscan2
- ITPRID2 | c.1086A>C p.E362D | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761720342, COSV57472046; called by muse, mutect2, varscan2
- KAT6B | c.3036G>A p.M1012I | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.577); catalogued as COSV99056191, COSV99768393; called by muse, mutect2
- LOXHD1 | c.5993C>T p.T1998M (on ENST00000642948; = p.T1936M on NM_144612.7) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs538782734, COSV56073238; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA2 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 12/366 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV65364430; called by muse, mutect2
- PCLO | c.7009G>A p.E2337K | Missense Mutation (SNP) | VAF 27/260 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs370714669; called by muse, mutect2
- RBM10 | c.1945C>T p.Q649* | Nonsense Mutation (SNP) | VAF 22/289 reads (8%) | catalogued as COSV61309381; called by muse, mutect2
- ADAMTS18 | c.1241G>C p.C414S | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA2D4 | c.1284C>G p.F428L | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CAMSAP3 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- CMTR2 | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 6/125 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2
- FAM186B | c.1629C>A p.S543R | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- FASTKD2 | c.1040_1043del p.H347Rfs*5 | Frame Shift Del (DEL) | VAF 21/206 reads (10%) | called by mutect2, pindel
- FLG | c.10537G>A p.A3513T | Missense Mutation (SNP) | VAF 41/407 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FZD6 | c.410_411del p.F137* | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | called by mutect2, pindel
- GCN1 | c.1614C>G p.A538= | Splice Region (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- GOLIM4 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HERC2 | c.10012G>T p.V3338F | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- INPP5J | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); called by muse, mutect2
- LAMA2 | c.7411G>C p.G2471R | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LPCAT1 | c.136-1G>A p.X46_splice | Splice Site (SNP) | VAF 12/80 reads (15%) | called by muse, mutect2
- MATK | c.1120G>A p.A374T (on ENST00000310132 / NM_139355.3; = p.A375T on NM_002378.4) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- NLRC4 | c.1211A>G p.H404R | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- PRKCG | c.1093G>T p.V365L | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- SLC12A5 | c.1819A>G p.T607A (on ENST00000454036 / NM_001134771.2; = p.T584A on NM_020708.5) | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2
- USH2A | c.5675T>A p.L1892Q | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- ZNF212 | c.660_681del p.Q221Rfs*17 | Frame Shift Del (DEL) | VAF 23/115 reads (20%) | called by mutect2, pindel
- DACT2 | c.2109C>T p.D703= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs748726350, COSV64694107, COSV64694270; called by muse, mutect2, varscan2
- DISC1 | c.201C>T p.F67= | Silent (SNP) | VAF 15/137 reads (11%) | catalogued as rs1184355977; called by muse, mutect2, varscan2
- GOLIM4 | c.522T>C p.T174= | Silent (SNP) | VAF 19/199 reads (10%) | called by muse, mutect2, varscan2
- IDS | c.633G>A p.K211= | Silent (SNP) | VAF 22/252 reads (9%) | catalogued as COSV61712429; called by muse, mutect2
- KCND2 | c.993C>A p.L331= | Silent (SNP) | VAF 11/263 reads (4%) | catalogued as rs1018289599; called by muse, mutect2
- KIF27 | c.2970C>T p.R990= | Silent (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- OR10H4 | c.391C>T p.L131= | Silent (SNP) | VAF 16/160 reads (10%) | called by muse, mutect2
- RBM10 | c.1944T>G p.A648= | Silent (SNP) | VAF 22/291 reads (8%) | called by muse, mutect2
- SP5 | c.870G>T p.P290= | Silent (SNP) | VAF 23/315 reads (7%) | called by muse, mutect2
- TNR | c.423C>T p.I141= | Silent (SNP) | VAF 25/252 reads (10%) | catalogued as rs1215247478, COSV54877160; called by muse, mutect2
- WFIKKN2 | c.114C>T p.I38= | Silent (SNP) | VAF 30/281 reads (11%) | called by muse, mutect2, varscan2
- ZDHHC4 | c.444C>T p.N148= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as rs746167960; called by muse, mutect2, varscan2
- EHMT2 | chr6:31901114 C>T | 5'Flank (SNP) | VAF 18/272 reads (7%) | catalogued as COSV64994051; called by muse, mutect2
- GABRA3 | c.551+4698C>A | Intron (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- MOGAT3 | chr7:101202209 G>A | 5'Flank (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- MORN1 | c.1250+3852G>A | Intron (SNP) | VAF 20/186 reads (11%) | catalogued as rs776165427; called by muse, mutect2, varscan2
- RRN3P1 | n.3188T>A | RNA (SNP) | VAF 50/277 reads (18%) | called by muse, mutect2, varscan2
- SERF2 | c.*31C>G | 3'UTR (SNP) | VAF 13/123 reads (11%) | called by muse, mutect2
